National Lung Screening Trial (NLST) participant 122226 — screening results, CT findings and lung cancer
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 66 years; Gender: female; Race: White; Cigarette smoking status at randomisation: current smoker; Enrolled through a Lung Screening Study (LSS) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; this participant has CT screening exam records, so these are low-dose CT screens)
- T0 (day 48): Positive, change unspecified: nodule(s) >= 4 mm or enlarging nodule(s), mass(es), or other non-specific abnormalities suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 80 mA, display field of view 30 cm, reconstruction filter Toshiba FC51.
- T1: No screening result: Not Expected - Cancer before screening window.
- T2: No screening result: Not Expected - Cancer before screening window.

Abnormalities recorded by the reading radiologist on the CT screens (5 abnormalities; numbered within each screening year; size, margins, attenuation and location were collected only for non-calcified nodules or masses of at least 4 mm; interval-change items come from the comparison read)
- T0 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left upper lobe; longest diameter 18 mm, longest perpendicular diameter 12 mm; margins spiculated (stellate); predominant attenuation soft tissue; greatest diameter on CT slice 16.
- T0 abnormality 2: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left upper lobe; longest diameter 8 mm, longest perpendicular diameter 7 mm; margins spiculated (stellate); predominant attenuation soft tissue; greatest diameter on CT slice 25.
- T0 abnormality 3: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left upper lobe; longest diameter 12 mm, longest perpendicular diameter 8 mm; margins spiculated (stellate); predominant attenuation soft tissue; greatest diameter on CT slice 34.
- T0 abnormality 4: Reticular/reticulonodular opacities, honeycombing, fibrosis, scar.
- T0 abnormality 5: Pleural thickening or effusion.

Lung cancer (2 primary lung cancer records; the first confirmed lung cancer followed a positive screen; study year of the first confirmed lung cancer: T0; the diagnosis is linked to a positive screen through the trial's diagnostic-procedure linking algorithm)
1. First primary lung cancer, diagnosed day 204, study year T0. Site: upper lobe of lung (ICD-O-3 C34.1), determined from histology. Primary tumour location: left upper lobe. Histology: adenocarcinoma, NOS (ICD-O-3 8140/3). Grade: moderately differentiated (G2). Tumour size on pathology: 17 mm. AJCC 6th edition staging: stage IB (best stage, from a mixture of clinical and pathologic TNM components); clinical T2 N0 M0 (stage IB); pathologic T2 NX MX. AJCC 7th edition staging: stage IB; clinical T1a N0 M0; pathologic T2a NX M0.
2. Subsequent primary lung cancer, diagnosed day 204, study year T0. Site: upper lobe of lung (ICD-O-3 C34.1), determined from histology. Histology: adenocarcinoma, NOS (ICD-O-3 8140/3). Grade: moderately differentiated (G2). Tumour size on pathology: 10 mm. AJCC 6th edition staging: stage IA (best stage, from a mixture of clinical and pathologic TNM components); clinical T1 N0 M0 (stage IA); pathologic T1 NX MX. AJCC 7th edition staging: stage IA; clinical T1a N0 M0; pathologic T1a NX M0.
